Surgical pathology report (de-identified scan), TCGA case TCGA-56-6545, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-6545-01A (Primary Tumor).

[page 1 of 3]
Collection Date: [REDACTED]
Hospital of Origin:
Copy to:

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Lymph nodes, level 7, excision:
Negative for malignancy, two nodes.

B. Lung, right upper lobe, lobectomy:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: 3 (poorly differentiated).
3. Tumor site: Subpleural.
4. Tumor focality: Unifocal
5. Tumor size: 5 x 5 x 3 cm
6. Visceral pleural invasion: not identified
7. Lymphovascular space invasion: not identified

Surgical Margin Status:

1. Tumor distance from bronchial margin: 3.0 cm.
2. Tumor distance from parenchymal (stapled) margin: 1.0 cm (grossly); microscopically, malignancy is present in and around an immediately adjacent bronchus (see comment).
3. Tumor distance from pleural surface: 0.1 cm.

Lymph Node Status:

1. Total number of lymph nodes received: (includes parts 1 and 3): Eleven.
2. Total number of lymph nodes containing metastatic carcinoma: Zero.

Other:

1. Other significant findings: A microscopic focus of invasive carcinoma, associated with bronchial squamous cell carcinoma in situ, is present in the section taken immediately adjacent to the stapled parenchymal margin (see comment).

A resected segment of rib is histologically unremarkable, with hematopoietic bone marrow and no evidence of primary or metastatic malignancy.

One hilar lymph node demonstrates a small, hyalinized, dystrophically calcified and inactive granuloma (see comment).

2. pTNM stage: pT2aN0.

C. Lymph nodes, level 4R, excision:
Negative for malignancy, two small nodes.

[page 2 of 3]
COMMENTS:

Histologic sections demonstrate a poorly differentiated malignancy, with extensive necrosis. Focally, convincing squamous differentiation is noted. No gland formation is appreciated. The malignancy focally extends to immediately beneath the surface of the visceral pleura. Areas of adhesion between visceral and parietal pleura are noted, and some portions of parietal pleura are present for evaluation.

These are uninvolved by the malignancy, as is the resected segment of rib.

The histologic appearance of localized squamous differentiation corresponds to changes noted in a prior fine needle aspiration biopsy, No history of

intervening treatment is received, however, the focally extensive necrosis in the malignancy could be the result of intervening treatment, and clinical correlation is suggested.

Bronchial and vascular margins are free of malignancy grossly and microscopically as are lymph nodes. There is, however, involvement of a bronchus at the stapled margin by both in situ, and focally invasive, carcinoma. Clinical correlation is suggested.

The granuloma present in one node appears inactive, and special stains for microorganisms will not be performed at this time, unless requested.

Sections have also been reviewed by Dr. [redacted] who is in agreement.

CLINICAL HISTORY:

Preoperative Diagnosis: [redacted] year old female with right lung cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Level 7 lymph nodes
- B. Right upper lobe with rib
- C. 4R lymph node

CODES:

PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [redacted]

Accession Date/Time: [redacted]

GROSS DESCRIPTION:

A. The first container A is labeled [redacted] level 7 lymph nodes. The specimen consists of two brown tan anthracotic nodules consistent with lymph nodes measuring 0.7 x 0.4 x 0.3 cm and 1.0 x 0.9 x 0.3 cm. The specimen is entirely submitted in a single cassette!

B. The second container B is labeled [redacted] right upper lobe with rib. The specimen consists of a lung

[page 3 of 3]
lobectomy specimen with attached rib measuring 13.0 x 12.0 x 5.0 cm and weighs 179 grams. The pleural surface is gray to brown tan and slightly anthracotic. There is an area of slight puckering of the pleural surface. The pleural surface has been inked black. The resected soft tissue margin of the attached rib has been inked blue. On sectioning the cut surface of the lung reveals a gray tan anthracotic mass measuring 5.0 x 5.0 x 3.0 cm that is within 0.1 cm of the pleural margin and is 3.0 cm of the bronchial margin of resection and 1.0 cm from the closest stapled edge. The mass displays central area of necrosis. The section of the rib measures 6.0 x 2.0 cm. On sectioning the cut surface of the rib is red tan. The rib overlies the mass. The mass does not appear to invade through the pleural surface. The mass comes within 1.5 cm of the resected surface of the rib and soft tissue. The rib is loosely attached to the pleural surface by soft tissue that appears unremarkable. The surrounding lung tissue is red to gray tan and spongy. There are no other lesions identified.

On sectioning through the peribronchial soft tissue reveals five probable lymph nodes measuring from 0.2 to 0.7 cm.

Received with the specimen are three cassettes, one green, one yellow, and one blue) labeled [REDACTED] Representative sections are submitted in cassettes [REDACTED] as follows:

rib margins after decalcification--1; rib in relationship to the mass after decalcification--2; sections from the mass--3 to 6; bronchial and vascular margin--7; shave section from the stapled margin--8; surrounding uninvolved lung--9; peribronchial lymph nodes submitted in toto as follows: four probable nodes--10; one probable node bisected--11.

C. The third container C is labeled [REDACTED], 4R lymph node. The specimen consists of two pieces of yellow tan soft tissue measuring 0.4 x 0.2 x 0.2 cm and 0.5 x 0.3 x 0.2 cm, entirely submitted in a single cassette

FULL RESULT:

Single view chest

Indication: Right pneumothorax.

Comparison: [REDACTED]

Findings: There is a new right chest tube. Vascular calcifications are noted. New patchy densities are seen in the right lung. Patient may have undergone right resection. Clinical correlation is recommended. I do not identify an endotracheal tube. No focal infiltrates on the left. There is a lucency in the right hemithorax. I cannot exclude pneumothorax.

IMPRESSION:

Right chest tube. Possible anterior right pneumothorax. Patchy atelectasis right lung. Possible postoperative change right lung. Correlation with any recent surgery is recommended.

Source: NCI Genomic Data Commons file 2b1a31d5-7834-4ea3-a319-936a131b3aeb (TCGA-56-6545.526BEB21-7FFD-4D23-A870-47FCC5EC6B73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).